Somatic mutation profile of tumor specimen TCGA-DX-A7EO-01A (aliquot TCGA-DX-A7EO-01A-11D-A36J-09) from TCGA case TCGA-DX-A7EO, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Synovial sarcoma, biphasic; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 20.8 years (7,604 days).
Specimen TCGA-DX-A7EO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df7d1838-9d33-40e4-87aa-b0a8137e3206.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A7EO-10A (Blood Derived Normal), aliquot TCGA-DX-A7EO-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8a5b269-1cad-4afb-8bf7-ad7665bcdc1e

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Frame Shift Del 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKFY1 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs765353710, COSV100492753; called by mutect2, varscan2
- CENPF | c.3551A>G p.E1184G | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV100871706; called by muse, mutect2, varscan2
- CSMD2 | c.2461G>A p.V821I | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.425); catalogued as COSV99590779; called by muse, mutect2, varscan2
- DENND4C | c.914A>G p.K305R | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.065); catalogued as COSV100991341; called by muse, mutect2, varscan2
- HMCN1 | c.564A>C p.E188D | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99629780; called by muse, mutect2, varscan2
- IL27 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.021); catalogued as COSV100795862; called by muse, mutect2, varscan2
- MGAT5 | c.1448G>A p.S483N | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as COSV99924541; called by muse, mutect2
- NXT2 | c.21T>A p.F7L (on ENST00000372106 / NM_001242617.2; = p.F62L on NM_018698.5) | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.749); catalogued as COSV99484141; called by muse, mutect2, varscan2
- PNLIPRP2 | c.1178G>A p.G393E (on ENST00000611850; = p.G394E on NM_005396.5) | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100077773; called by muse, mutect2, varscan2
- SORCS3 | c.1838T>A p.F613Y | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV100865179; called by muse, mutect2, varscan2
- TM4SF1 | c.252_253del p.C84Wfs*39 | Frame Shift Del (DEL) | VAF 16/32 reads (50%) | catalogued as rs1443968832; called by pindel, varscan2
- DPP3 | c.157_192del p.S53_S64del | In Frame Del (DEL) | VAF 14/36 reads (39%) | called by mutect2, pindel
- CA8 | c.300G>A p.S100= | Silent (SNP) | VAF 13/142 reads (9%) | catalogued as rs749173414, COSV100526643, COSV58772456; called by muse, mutect2
- FAN1 | c.2208G>A p.P736= | Silent (SNP) | VAF 6/83 reads (7%) | catalogued as rs141117593; called by muse, mutect2
- OAS2 | c.441C>T p.N147= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs369863340; called by muse, mutect2, varscan2
- ETFB | c.58-65C>T | Intron (SNP) | VAF 9/61 reads (15%) | catalogued as rs143544475; called by muse, mutect2, varscan2
